EXCEPTIONAL_RESPONDERS case ER-B0DO — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/51343e16-05b6-4314-8169-59ff765bda0a

Demographics
Sex at birth: female; Race: white; Year of birth: 1959; Vital status: Alive.

Diagnoses (1)
1. Glioblastoma multiforme: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 49.4 years (18,038 days); Year of diagnosis: 2008; Prior malignancy: no; Days to last follow up: 3,269 days (9.0 years); Days to best overall response: 204 days; Best overall response: Partial Response.
   Treatment given: Therapeutic agents: Temozolomide; Days to treatment start: 130 days.

Follow-up (1 entry)
- Days to follow up: 3,269 days (9.0 years); Disease response: Stable Disease; Progression or recurrence: No; Days progression-free: 3,269 days (9.0 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-B0DO-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-B0DO-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 83; Percent tumor nuclei: 90; Percent normal cells: 1; Percent necrosis: 15; Percent stromal cells: 1; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
